Gene-level copy-number profile of tumor specimen ALCH-AEKI-TTP1-A from ALCHEMIST case ALCH-AEKI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.0 years (22,295 days).
Specimen ALCH-AEKI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 82ff6d76-b151-44aa-afe1-d6386ae6a2ef.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEKI-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/e144f1f2-b5e9-4ffe-bc06-e2e7abcdfd07

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 7,081; copy number 2: 47,475; copy number 3: 4,257; copy number 4: 44; copy number 5: 12; copy number 6: 4.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:241,010,045–241,010,744, 1 gene (within-gene range 0–1): AC093585.1.
- chr4:3,758,748–3,763,390, 1 gene: LINC02600.
- chr11:127,204–139,612, 1 gene (within-gene range 0–2): LINC01001.
- chr14:104,085,686–104,117,514, 3 genes: ASPG, MIR203A, MIR203B.
- chr15:25,180,497–25,215,622, 20 genes (within-gene range 0–2): SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25.
- chr16:88,382,959–88,440,757, 1 gene: ZNF469.
- chr22:49,264,201–49,266,080, 1 gene: Z82202.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:26,158,146–26,206,038, 12 genes, copy number 5: H2BC5, AL353759.1, LARP1P1, H2BC6, H4C4, H1-12P, AL031777.2, H3C4, H2AC7, H2BC7, AL031777.1, H4C5.
- chr9:61,868,727–61,887,084, 2 genes, copy number 6: AL391987.3, Y_RNA.
- chr11:112,967–126,123, 2 genes, copy number 6: AC069287.1, CICP23.

Autosomal genes at a single copy (total copy number 1): 4,254. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
